Somatic mutation profile of tumor specimen MMRF_1568_1_BM_CD138pos (aliquot MMRF_1568_1_BM_CD138pos_T1_KBS5U_L05379) from MMRF case MMRF_1568, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.8 years (24,411 days).
Specimen MMRF_1568_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 660ef1d7-fb6e-494f-855d-78ec3e168a51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1568_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1568_1_PB_Whole_C2_KBS5U_L05392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51cdc67b-c1f2-49f3-bca6-36115cc3589e

The open-access MAF lists 161 somatic variants for this specimen: 66 protein-altering or splice-affecting, 19 silent, 76 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, 3'UTR 37, Silent 19, Intron 18, 5'UTR 10, RNA 7, Nonsense Mutation 5, 3'Flank 2, Splice Region 2, 5'Flank 2, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABTB2 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1428655784, COSV54388033; called by muse, mutect2, varscan2
- CACNA1A | c.1392G>T p.E464D | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.673); catalogued as COSV64200013; called by muse, mutect2, varscan2
- CASKIN1 | c.1013C>A p.P338Q | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100624494; called by muse, mutect2, varscan2
- CFAP299 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 82/169 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as rs765782959, COSV63872319; called by muse, mutect2, varscan2
- FPR1 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.607); catalogued as rs752751969, COSV59053626; called by muse, mutect2, varscan2
- GALR1 | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as rs144878705; called by muse, mutect2, varscan2
- GCAT | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs772113575; called by muse, mutect2, varscan2
- LAG3 | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 14/102 reads (14%) | catalogued as rs1183837540; called by muse, mutect2, varscan2
- MAX | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52416276, COSV52416985, COSV52418829; called by muse, mutect2, varscan2
- MAX | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV52419294; called by muse, mutect2, varscan2
- NCOR2 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs368778412; called by muse, mutect2, varscan2
- NOVA1 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV57472929; called by muse, mutect2, varscan2
- NSD1 | c.6887T>C p.V2296A | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs754309202; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR5D18 | c.340T>A p.F114I | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as COSV61736553, COSV61739035; called by muse, mutect2, varscan2
- OR5I1 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100041163; called by muse, mutect2, varscan2
- SH3PXD2B | c.1391C>T p.T464M | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs550449429; called by muse, mutect2
- SQLE | c.11T>C p.F4S | Missense Mutation (SNP) | VAF 87/329 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs1264153723; called by muse, mutect2, varscan2
- SRSF7 | c.49A>T p.N17Y | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57447535; called by muse, mutect2, varscan2
- TPSD1 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as rs200938484; called by muse, mutect2, varscan2
- TRPS1 | c.845T>G p.V282G (on ENST00000220888 / NM_001330599.2; = p.V295G on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/111 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1316599674, COSV55232160; called by muse, varscan2
- TTLL13P | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs370969414; called by muse, mutect2, varscan2
- ZC3H12C | c.2287C>T p.R763* | Nonsense Mutation (SNP) | VAF 34/329 reads (10%) | catalogued as COSV99584570; called by muse, mutect2, varscan2
- ABCC9 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ADCY3 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- ADGRB3 | c.2850T>A p.F950L | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGAP24 | c.1707C>A p.N569K (on ENST00000395184 / NM_001025616.3; = p.N476K on NM_031305.3) | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ARSB | c.344G>A p.W115* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- BEND3 | c.356G>A p.C119Y | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BIRC6 | c.4631T>G p.V1544G | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMPR2 | c.2549A>C p.Q850P | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- CACNA1I | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- DIS3 | c.1430G>T p.S477I | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPP8 | c.1955A>G p.K652R (on ENST00000341861 / NM_001320875.2; = p.K636R on NM_017743.6) | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ERICH3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FREM3 | c.1886G>T p.W629L | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRE | c.1297A>G p.S433G | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HCFC2 | c.287dup p.Y96* | Nonsense Mutation (INS) | VAF 38/194 reads (20%) | called by mutect2, pindel, varscan2
- IRAG2 | c.3861G>A p.M1287I (on ENST00000636465; = p.M332I on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- KLHL38 | c.344A>T p.Q115L | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- LMLN | c.905A>C p.D302A | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MAGEB6B | c.1019A>G p.K340R | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- MAGEB6B | c.1166A>G p.H389R | Missense Mutation (SNP) | VAF 88/297 reads (30%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- MEIS1 | c.1114+7C>A | Splice Region (SNP) | VAF 31/239 reads (13%) | called by muse, mutect2, varscan2
- MOCOS | c.2094del p.F698Lfs*7 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | called by mutect2, pindel, varscan2
- NCBP1 | c.1214T>C p.M405T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NFASC | c.1682A>G p.D561G (on ENST00000339876 / NM_001378329.1; = p.D572G on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, varscan2
- NXF3 | c.621G>A p.K207= | Splice Region (SNP) | VAF 25/97 reads (26%) | called by muse, mutect2, varscan2
- OTOGL | c.5695A>G p.I1899V (on ENST00000547103; = p.I1890V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.029); called by muse, mutect2
- PCDHA10 | c.2332C>A p.P778T | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PTPRD | c.229G>T p.G77W | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAB41 | c.611G>T p.G204V (on ENST00000374473 / NM_001363807.1; = p.G203V on NM_001032726.3) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, varscan2
- RBM27 | c.2290C>T p.H764Y | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUBCNL | c.109C>A p.H37N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SGPP2 | c.558G>T p.Q186H | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- SORL1 | c.3195G>T p.Q1065H | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- STEAP3 | c.983C>A p.A328D | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TAF6 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TCTN2 | c.1970C>G p.T657S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); called by muse, mutect2
- TRAF3 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRPM8 | c.775C>A p.H259N | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TXNDC5 | c.1125G>C p.K375N | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- USP22 | c.755C>A p.A252E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR33 | c.2756A>G p.N919S | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZC2HC1C | c.1365G>A p.W455* | Nonsense Mutation (SNP) | VAF 76/77 reads (99%) | called by muse, mutect2, varscan2
- ZNF275 | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ADARB2 | c.1275G>A p.G425= | Silent (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- AOC2 | c.2241C>T p.D747= (on ENST00000253799 / NM_009590.4; = p.D720= on NM_001158.5) | Silent (SNP) | VAF 112/227 reads (49%) | catalogued as rs767601829; called by muse, mutect2, varscan2
- BACH2 | c.1350G>T p.G450= | Silent (SNP) | VAF 54/257 reads (21%) | catalogued as rs777755082; called by muse, mutect2, varscan2
- CASKIN1 | c.1014G>T p.P338= | Silent (SNP) | VAF 41/170 reads (24%) | called by muse, mutect2, varscan2
- FILIP1L | c.2886T>C p.S962= (on ENST00000354552 / NM_182909.3; = p.S722= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 102/205 reads (50%) | called by muse, mutect2, varscan2
- FSD1 | c.1116C>T p.G372= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs367629466; called by muse, mutect2, varscan2
- HAUS6 | c.2292T>C p.S764= | Silent (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2, varscan2
- JADE3 | c.1704C>T p.D568= | Silent (SNP) | VAF 55/183 reads (30%) | called by muse, mutect2, varscan2
- KCNB2 | c.460C>A p.R154= | Silent (SNP) | VAF 99/214 reads (46%) | catalogued as COSV73049818; called by muse, mutect2, varscan2
- KRT5 | c.1203C>T p.D401= | Silent (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- NOS2 | c.375G>A p.L125= | Silent (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2
- PLEKHS1 | c.1095G>C p.L365= | Silent (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- PTH | c.189C>T p.H63= | Silent (SNP) | VAF 29/212 reads (14%) | called by muse, mutect2, varscan2
- RFC2 | c.906G>A p.V302= (on ENST00000055077 / NM_181471.3; = p.V268= on NM_002914.4) | Silent (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- SLC27A6 | c.849C>T p.A283= | Silent (SNP) | VAF 47/101 reads (47%) | catalogued as rs1326776153, COSV52488825; called by muse, mutect2, varscan2
- WDR11 | c.1602C>A p.T534= | Silent (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- ZNF83 | c.1446G>A p.E482= | Silent (SNP) | VAF 25/107 reads (23%) | called by muse, mutect2, varscan2
- ZNF90 | c.1755G>A p.R585= | Silent (SNP) | VAF 59/232 reads (25%) | catalogued as rs782496078; called by muse, mutect2, varscan2
- ZP4 | c.345T>A p.A115= | Silent (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2
- AC024651.2 | n.519C>A | RNA (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- AC112721.1 | n.252G>A | RNA (SNP) | VAF 38/122 reads (31%) | catalogued as rs924555112; called by muse, mutect2, varscan2
- ACSS2 | chr20:34875058 G>C | 5'Flank (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- ALCAM | c.-334_-332del | 5'UTR (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- AMD1 | c.*1306T>C | 3'UTR (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- ARHGAP9 | c.-204+589G>A | Intron (SNP) | VAF 34/137 reads (25%) | catalogued as COSV100007559, COSV56258377; called by muse, mutect2, varscan2
- BEND2 | c.*464A>C | 3'UTR (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- BRWD1 | c.6571+717A>G | Intron (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- CCNJL | c.888-704A>G | Intron (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- CD34 | c.598-601A>T | Intron (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- CDK2AP2 | chr11:67508385 G>C | 5'Flank (SNP) | VAF 7/87 reads (8%) | catalogued as rs1408442195; called by muse, mutect2
- CLK2P1 | n.811C>G | RNA (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- COL17A1 | c.1222+180G>T | Intron (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- CTNNA3 | c.*140C>T | 3'UTR (SNP) | VAF 21/65 reads (32%) | catalogued as rs867026784; called by muse, mutect2, varscan2
- DLGAP2 | c.*6060C>A | 3'UTR (SNP) | VAF 17/118 reads (14%) | catalogued as rs867602033; called by muse, mutect2, varscan2
- DMAC2 | c.18+10C>T | Intron (SNP) | VAF 25/54 reads (46%) | catalogued as rs781993079; called by muse, mutect2, varscan2
- DNAJC12 | c.297+24G>A | Intron (SNP) | VAF 73/151 reads (48%) | catalogued as rs748635046, COSV56546886; called by muse, mutect2, varscan2
- ERBB4 | c.*6814T>C | 3'UTR (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- ERBB4 | c.*3696G>C | 3'UTR (SNP) | VAF 31/135 reads (23%) | catalogued as COSV61459609; called by muse, mutect2, varscan2
- FGF2 | c.*258G>A | 3'UTR (SNP) | VAF 15/92 reads (16%) | catalogued as rs1394793361; called by muse, mutect2, varscan2
- FMNL2 | c.3169+116T>A | Intron (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- FRK | c.-271G>T | 5'UTR (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2, varscan2
- GABRQ | c.*1016T>C | 3'UTR (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- GNB1L | c.*1459A>G | 3'UTR (SNP) | VAF 33/172 reads (19%) | called by muse, mutect2, varscan2
- GNPDA2 | c.770-1008A>G | Intron (SNP) | VAF 23/87 reads (26%) | catalogued as rs1252576799; called by muse, mutect2, varscan2
- HERC4 | c.*372C>T | 3'UTR (SNP) | VAF 5/129 reads (4%) | called by muse, mutect2
- HERC4 | c.*371G>T | 3'UTR (SNP) | VAF 5/130 reads (4%) | called by muse, mutect2
- HLA-DOA | c.*2362C>A | 3'UTR (SNP) | VAF 26/98 reads (27%) | called by muse, mutect2, varscan2
- HMGA2 | c.249+20058T>A | Intron (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- HNRNPD | c.-111T>C | 5'UTR (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- HPSE | c.*2221A>G | 3'UTR (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- IGF1R | c.*3166G>T | 3'UTR (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- KDM1A | c.-91C>G | 5'UTR (SNP) | VAF 23/91 reads (25%) | called by muse, mutect2, varscan2
- KIAA0825 | c.*494_*497del | 3'UTR (DEL) | VAF 18/87 reads (21%) | called by mutect2, pindel, varscan2
- LINC01299 | n.2081T>C | RNA (SNP) | VAF 23/105 reads (22%) | called by muse, mutect2, varscan2
- LPAR6 | c.-363A>T | 5'UTR (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- LRRD1 | chr7:92142668 C>T | 3'Flank (SNP) | VAF 18/37 reads (49%) | catalogued as rs1007657159; called by muse, mutect2, varscan2
- MARCHF4 | c.-1528C>A | 5'UTR (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- MARK1 | c.*1844G>C | 3'UTR (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2
- MTSS1 | c.*1751G>A | 3'UTR (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- MZT2A | n.627C>A | RNA (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.760C>A | RNA (SNP) | VAF 52/108 reads (48%) | called by muse, mutect2, varscan2
- NRK | c.-228A>C | 5'UTR (SNP) | VAF 16/302 reads (5%) | called by muse, mutect2
- NRP1 | c.981+4574G>A | Intron (SNP) | VAF 36/281 reads (13%) | catalogued as rs1054191665; called by muse, mutect2, varscan2
- OR2T2 | chr1:248453831 C>A | 3'Flank (SNP) | VAF 39/259 reads (15%) | called by muse, varscan2
- OR4S2 | c.*26G>A | 3'UTR (SNP) | VAF 60/229 reads (26%) | called by muse, mutect2, varscan2
- PATJ | c.*375T>G | 3'UTR (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- PIM1 | c.-125_-102del | 5'UTR (DEL) | VAF 23/85 reads (27%) | catalogued as rs779716961; called by mutect2, varscan2
- PLAAT3 | c.*69G>C | 3'UTR (SNP) | VAF 112/469 reads (24%) | called by muse, mutect2, varscan2
- PLEKHN1 | c.*7C>T | 3'UTR (SNP) | VAF 26/50 reads (52%) | catalogued as rs199696862; called by muse, mutect2, varscan2
- PPFIA2 | c.1131+55C>A | Intron (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- PRICKLE2 | c.42+34C>G | Intron (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- RAG1 | c.*3090G>C | 3'UTR (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- RNF130 | c.*757G>A | 3'UTR (SNP) | VAF 37/127 reads (29%) | catalogued as rs909776131; called by muse, mutect2, varscan2
- SAMD5 | c.*844C>T | 3'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as rs1319201275; called by muse, mutect2
- SEPTIN9 | c.76+13124_76+13172del | Intron (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- SGCA | c.*129G>A | 3'UTR (SNP) | VAF 29/184 reads (16%) | called by muse, mutect2, varscan2
- SLITRK2 | c.-1973C>T | 5'UTR (SNP) | VAF 37/207 reads (18%) | called by muse, mutect2, varscan2
- SNX22 | c.265-22A>C | Intron (SNP) | VAF 27/136 reads (20%) | called by muse, mutect2, varscan2
- SPATA13 | c.*2602G>C | 3'UTR (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- SSH1 | c.*2367A>T | 3'UTR (SNP) | VAF 34/145 reads (23%) | called by muse, mutect2, varscan2
- TDGF1 | c.-16C>T | 5'UTR (SNP) | VAF 66/365 reads (18%) | called by muse, mutect2, varscan2
- THAP2 | c.71+767A>G | Intron (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- THEMIS | c.*545A>G | 3'UTR (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- TNS1 | c.*3844C>T | 3'UTR (SNP) | VAF 50/196 reads (26%) | called by muse, mutect2, varscan2
- TP63 | c.*7C>G | 3'UTR (SNP) | VAF 21/73 reads (29%) | called by muse, mutect2, varscan2
- TRHDE | c.*2091C>T | 3'UTR (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- U82695.1 | n.1776C>T | RNA (SNP) | VAF 92/428 reads (21%) | called by muse, mutect2, varscan2
- YOD1 | c.*3152A>G | 3'UTR (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- ZFHX3 | c.*265A>T | 3'UTR (SNP) | VAF 14/33 reads (42%) | called by muse, varscan2
- ZFHX3 | c.*183A>T | 3'UTR (SNP) | VAF 16/31 reads (52%) | called by muse, varscan2
- ZFPM2 | c.740-2963C>T | Intron (SNP) | VAF 6/21 reads (29%) | catalogued as rs772305890; called by muse, mutect2, varscan2
- ZNF135 | c.33+52T>C | Intron (SNP) | VAF 47/159 reads (30%) | catalogued as rs1330003310, COSV100536357; called by muse, mutect2, varscan2
- ZNF516 | c.*2268G>T | 3'UTR (SNP) | VAF 33/122 reads (27%) | called by muse, mutect2, varscan2
- ZNF704 | c.*7126G>T | 3'UTR (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- ZNF716 | c.*522T>A | 3'UTR (SNP) | VAF 34/133 reads (26%) | called by muse, mutect2, varscan2
